Somatic mutation profile of tumor specimen TARGET-10-PATBGC-09A (aliquot TARGET-10-PATBGC-09A-01D) from TARGET case TARGET-10-PATBGC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.8 years (3,946 days).
Specimen TARGET-10-PATBGC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c6302c5-8eef-4e2d-86b0-d7980be6a1e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATBGC-10A (Blood Derived Normal), aliquot TARGET-10-PATBGC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbe03456-4b9d-4821-bb7e-c4ecd4097f4b

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Intron 2, RNA 1, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BAAT | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768526453, COSV52290567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DENND1C | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as rs375160320; called by muse, mutect2, varscan2
- DSC1 | c.2392C>A p.Q798K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as COSV57151072, COSV57151466; called by muse, mutect2, varscan2
- IKZF1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58783774; called by muse, mutect2, varscan2
- MFN1 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs200358054, COSV54942312; called by muse, mutect2, varscan2
- MXRA5 | c.5767C>T p.R1923* | Nonsense Mutation (SNP) | VAF 36/74 reads (49%) | catalogued as rs527784574, COSV54222197; called by muse, mutect2, varscan2
- SORBS2 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs954590355, COSV53013905; called by muse, mutect2, varscan2
- TNMD | c.17C>A p.P6Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.937); catalogued as COSV65977759; called by muse, mutect2, varscan2
- USP29 | c.2101G>A p.V701I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.877); catalogued as rs570824915, COSV54146343; called by muse, mutect2, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 18/40 reads (45%) | called by mutect2, varscan2
- CNTNAP3B | c.1757-1G>T p.X586_splice | Splice Site (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- DCHS1 | c.2956del p.V986Wfs*75 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | called by mutect2, varscan2
- ZSCAN5A | c.1246G>T p.V416F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- DYNC1I1 | c.345C>T p.G115= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs145885345; called by muse, mutect2, varscan2
- FGD3 | c.672G>A p.T224= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs764785925, COSV100490741; called by muse, mutect2, varscan2
- TRPC7 | c.1359C>T p.S453= | Silent (SNP) | VAF 55/100 reads (55%) | called by muse, mutect2, varscan2
- CRYZL1 | c.904+145T>C | Intron (SNP) | VAF 23/37 reads (62%) | called by muse, mutect2, varscan2
- DSC1 | c.2487+81C>A | Intron (SNP) | VAF 14/26 reads (54%) | called by mutect2, varscan2
- OR2U1P | n.502G>A | RNA (SNP) | VAF 30/50 reads (60%) | catalogued as rs371770116; called by muse, mutect2, varscan2
